Surgical pathology report (de-identified scan), TCGA case TCGA-19-1389, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1389-01A (Primary Tumor).

[page 1 of 2]
SEX: M

SURGICAL PATHOLOGY

PAGE 001 OF 006 FOR TEST 001 OF 001

Accession #:

Pathologist:

Date Reported:

Date Received:

Submitting Physician:

FINAL DIAGNOSIS

A. ANTERIOR/SUPERIOR TIP OF NEOPLASM, BIOPSY:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV.)

B. TEMPORAL TIP, EXCISION:
--CEREBRAL CORTEX AND WHITE MATTER WITH REACTIVE FEATURES.

C. POSSIBLE EDGE OF TUMOR, EXCISION:

ENTER=CONTINUE

F1=HELP

F2=

F3=

F4=

F5=PAT SEL

F6=EXAM SUM.

F7=

F8=NEXT PAGE

F11=MORE FKEYS

[page 2 of 2]
RESULTS DETAIL

TERM:

SEX: M

URGICAL PATHOLOGY
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV.)

PAGE 002 OF 006 FOR TEST 001 OF 001

D. TUMOR, EXCISION:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV.)

Electronically Signed Out By

Intraoperative Consult Diagnosis

A. Touch Imprint and Microscopic: High-grade glial neoplasm. Dr.

ENTER=CONTINUE	F1=HELP	F2=	F3=	F4=
F5=PAT SEL	F6=EXAM SUM.	F7=PREV PAGE	F8=NEXT PAGE	F11=MORE FKEYS

Source: NCI Genomic Data Commons file 4266e28e-067c-4b3d-802a-e285068cf972 (TCGA-19-1389.FFB02D1A-1D35-4287-B2FF-F77A258A984D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).